TCGA case TCGA-08-0373 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cf6c734-74c3-4fb5-ac4b-72967edd6ee7

Demographics
Sex at birth: male; Age at index: 69 years; Vital status: Dead; Days to death: 134 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,274 days); Year of diagnosis: 1994; Method of diagnosis: Surgical Resection; Prior treatment: No.

Follow-up (1 entry)
- Days to follow up: 134 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.6.
  Slide TCGA-08-0373-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 50; Percent stromal cells: 10.
  Slide TCGA-08-0373-01A-01-BS1: Section location: Bottom; Percent tumor cells: 45; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 50; Percent stromal cells: 5.
- Sample TCGA-08-0373-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0373-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 134 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 134 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 134 days.
